Gene-level copy-number profile of tumor specimen TCGA-BC-A10W-01A from TCGA case TCGA-BC-A10W, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G3; Age at diagnosis: 50.8 years (18,562 days).
Specimen TCGA-BC-A10W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.49339303-3497-4557-9cb4-4866ffc68365.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A10W-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0ee866f2-c554-4355-a555-31ddba745b3a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,964; copy number 2: 40,149; copy number 3: 4,896; copy number 4: 2; copy number 5: 1,523; copy number 6: 1,714; copy number 8: 34; copy number 9: 1,538.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A10W-01A-11D-A12Y-01): tumor purity 0.73, ploidy 2.28, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,809 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:42,176,539–210,676,296, 3,286 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr1:210,678,315–210,681,932, 1 gene, copy number 6: AC096636.1.
- chr1:210,859,177–210,862,285, 1 gene, copy number 6: IPO8P1.
- chr8:69,834,111–145,066,685, 1,183 genes, copy number 6 (broad region; genes not listed).
- chr13:95,578,202–114,337,626, 298 genes, copy number 9 (broad region; genes not listed).
- chr16:46,469,341–47,464,149, 32 genes, copy number 6–8: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA.
- chr16:47,505,432–47,566,884, 4 genes, copy number 8: RNA5SP425, AC007599.2, AC007599.1, EIF4BP5.
- chr16:70,802,084–71,230,722, 4 genes, copy number 5 (within-gene range 1–5): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.

Autosomal genes at a single copy (total copy number 1): 7,577. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
